Somatic mutation profile of tumor specimen TCGA-S8-A6BV-01A (aliquot TCGA-S8-A6BV-01A-21D-A31U-09) from TCGA case TCGA-S8-A6BV, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 77.0 years (28,111 days).
Specimen TCGA-S8-A6BV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f80ff4ac-011b-48f1-a4bc-7bd72c1ac653.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-S8-A6BV-10A (Blood Derived Normal), aliquot TCGA-S8-A6BV-10A-01D-A31U-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8aa74c0f-991e-479a-95c3-13c1e0c7342c

The open-access MAF lists 124 somatic variants for this specimen: 89 protein-altering or splice-affecting, 33 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 79, Silent 33, Nonsense Mutation 6, Splice Region 1, RNA 1, Intron 1, Splice Site 1, Frame Shift Del 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LYST | c.1507C>T p.R503* | Nonsense Mutation (SNP) | VAF 6/32 reads (19%) | catalogued as rs1558282769, CM132323; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTPRT | c.2002T>G p.L668V | Missense Mutation (SNP) | VAF 24/57 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.175); catalogued as COSV61957384, COSV61969153; called by muse, mutect2, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 22/53 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAM19 | c.353C>T p.T118M | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.034); catalogued as rs952947999, COSV57435158, COSV99978504; called by muse, mutect2, varscan2
- ADGRL3 | c.1589G>A p.R530K (on ENST00000506720 / NM_001322402.2; = p.R462K on NM_015236.6) | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV101547383; called by muse, mutect2, varscan2
- AGMO | c.248G>A p.R83Q | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as rs373631505; called by muse, mutect2, varscan2
- ALDH6A1 | c.740T>G p.F247C | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as rs1427633998, COSV63246105; called by muse, mutect2, varscan2
- ANKEF1 | c.1663G>A p.D555N | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1350910159; called by muse, mutect2, varscan2
- ASIC1 | c.617G>A p.R206Q | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.122); catalogued as rs762242221; called by muse, mutect2, varscan2
- ATIC | c.287T>C p.I96T | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs759249668; called by mutect2, varscan2
- BMP15 | c.610C>T p.R204* | Nonsense Mutation (SNP) | VAF 9/27 reads (33%) | catalogued as rs991314787, COSV53140530; called by muse, mutect2, varscan2
- C2CD2L | c.1817G>A p.R606H | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.909); catalogued as rs376731505; called by muse, mutect2, varscan2
- CD1E | c.445A>T p.S149C | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV63769868; called by muse, mutect2, varscan2
- CDH17 | c.1009C>T p.P337S | Missense Mutation (SNP) | VAF 13/140 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.1); catalogued as rs751015132; called by muse, mutect2
- CIZ1 | c.2545G>A p.A849T | Missense Mutation (SNP) | VAF 41/232 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs1488298275; called by muse, mutect2, varscan2
- CLK4 | c.349C>T p.R117C | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.27); catalogued as rs752872069, COSV60319307; called by muse, mutect2, varscan2
- CNST | c.323T>A p.I108N | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.6); PolyPhen benign (0.157); catalogued as rs757771014, COSV63620327; called by muse, mutect2, varscan2
- CSMD1 | c.6616G>A p.G2206S (on ENST00000520002; = p.G2205S on NM_033225.6) | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766680987, COSV59322798; called by muse, mutect2, varscan2
- DZIP3 | c.872G>T p.C291F | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.355); catalogued as COSV64312509; called by muse, mutect2, varscan2
- EID2B | c.485G>C p.*162Sext*12 | Nonstop Mutation (SNP) | VAF 9/33 reads (27%) | catalogued as rs768803088; called by muse, mutect2, varscan2
- FPR1 | c.379G>A p.V127I | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.954); catalogued as rs186613919; called by muse, mutect2, varscan2
- IRX1 | c.1180G>A p.V394I | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV57359216; called by mutect2, varscan2
- KCNN4 | c.1199C>T p.A400V | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.054); catalogued as rs954068767; called by muse, mutect2, varscan2
- LCE1D | c.277A>C p.S93R | Missense Mutation (SNP) | VAF 9/105 reads (9%) | PolyPhen benign (0.003); catalogued as COSV58272060; called by muse, mutect2
- MAP1S | c.2969G>A p.R990Q | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.407); catalogued as rs759351694, COSV60725167; called by muse, mutect2, varscan2
- MAT2B | c.443G>A p.R148K | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs544029890; called by muse, mutect2, varscan2
- MYMK | c.135G>A p.A45= | Splice Region (SNP) | VAF 6/48 reads (13%) | catalogued as rs777300317, COSV101301172; called by mutect2, varscan2
- NDUFA4 | c.233G>A p.R78H | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as rs1286100412, COSV60011788; called by muse, mutect2, varscan2
- NOMO1 | c.2734G>A p.G912S | Missense Mutation (SNP) | VAF 28/203 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs369439386; called by muse, mutect2, varscan2
- NPBWR2 | c.719G>A p.R240Q | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.847); catalogued as rs139565347; called by muse, mutect2, varscan2
- ONECUT2 | c.1436G>A p.R479H | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1395310520; called by muse, mutect2, varscan2
- OR5D13 | c.217T>G p.F73V | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.103); catalogued as COSV62333075; called by muse, mutect2, varscan2
- PATE1 | c.8A>C p.K3T | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.269); catalogued as COSV59825423, COSV99986280; called by muse, mutect2, varscan2
- PCDHA4 | c.22G>A p.G8S | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.006); catalogued as rs782421232, COSV100793826, COSV63541255; called by muse, mutect2, varscan2
- PCGF5 | c.110C>T p.T37I | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.68); catalogued as rs1431307337; called by muse, mutect2, varscan2
- POTEF | c.2183G>A p.R728Q | Missense Mutation (SNP) | VAF 24/142 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.735); catalogued as rs755975114, COSV62541232; called by muse, mutect2, varscan2
- PXDN | c.1207G>A p.V403I | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as rs146093600, COSV99412259; called by mutect2, varscan2
- RELN | c.3161A>G p.Y1054C | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.594); catalogued as COSV59000032; called by muse, mutect2, varscan2
- SCN9A | c.3868C>T p.R1290W (on ENST00000303354; = p.R1279W on NM_002977.3) | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763423536, COSV57613614; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SETX | c.3931C>T p.R1311C | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773999398; called by muse, mutect2, varscan2
- SIDT1 | c.1639G>A p.A547T | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.495); catalogued as rs144146634; called by muse, mutect2, varscan2
- SLC17A4 | c.1010C>T p.P337L | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.911); catalogued as rs368361659, COSV64956094; called by muse, mutect2, varscan2
- SLC6A12 | c.458C>T p.P153L | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1475863358; called by muse, mutect2, varscan2
- STEAP3 | c.587C>T p.A196V | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs753458208, COSV61530903; called by muse, mutect2, varscan2
- TMEM132D | c.1723G>A p.A575T | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.914); catalogued as rs775400147; called by muse, mutect2, varscan2
- TRAM1L1 | c.805G>A p.V269I | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.179); catalogued as rs762544664, COSV60292194; called by muse, mutect2
- ZFHX4 | c.9606C>G p.I3202M | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.718); catalogued as COSV50490279; called by muse, mutect2, varscan2
- ZNF721 | c.1442G>C p.R481T (on ENST00000338977; = p.R493T on NM_133474.4) | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.989); catalogued as COSV59097093; called by muse, mutect2, varscan2
- ZNF750 | c.1123G>A p.V375I | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs769781285; called by muse, mutect2, varscan2
- ACSS1 | c.449C>G p.T150R | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ALDH1A1 | c.1304A>C p.K435T | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT deleterious (0.04); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- AMY2B | c.1126C>A p.P376T | Missense Mutation (SNP) | VAF 23/358 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- ARHGAP45 | c.470C>G p.A157G | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CASS4 | c.797A>G p.E266G | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CDRT1 | c.1171G>T p.V391F | Missense Mutation (SNP) | VAF 20/125 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.441); called by muse, mutect2, varscan2
- CLEC4F | c.209C>T p.P70L | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- CPO | c.1093G>A p.G365S | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- CYP4B1 | c.1030G>T p.E344* | Nonsense Mutation (SNP) | VAF 6/48 reads (13%) | called by muse, mutect2
- DENND11 | c.963G>T p.E321D | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- DSCC1 | c.1138C>G p.Q380E | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.155); called by muse, mutect2
- FUCA2 | c.273A>C p.K91N | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- HIPK1 | c.2411G>A p.S804N | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT tolerated (1); PolyPhen possibly damaging (0.878); called by muse, mutect2
- HMCN1 | c.11834G>C p.R3945T | Missense Mutation (SNP) | VAF 39/85 reads (46%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- IGKV2D-28 | c.205C>G p.P69A | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.279); called by mutect2, varscan2
- JAKMIP1 | c.2219A>G p.Q740R | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KRT85 | c.1299-2A>C p.X433_splice | Splice Site (SNP) | VAF 8/37 reads (22%) | called by muse, mutect2, varscan2
- LATS2 | c.2537C>T p.S846F | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- LRP1B | c.12626A>G p.D4209G | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.305); called by muse, mutect2, varscan2
- MAP3K10 | c.2794C>A p.L932M | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- MFSD12 | c.980C>A p.S327Y | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); called by mutect2, varscan2
- MRC1 | c.2430C>A p.Y810* | Nonsense Mutation (SNP) | VAF 123/378 reads (33%) | called by muse, mutect2, varscan2
- MUC16 | c.1510del p.D504Tfs*3 | Frame Shift Del (DEL) | VAF 11/54 reads (20%) | called by mutect2, pindel, varscan2
- MYH6 | c.2276A>C p.K759T | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.765); called by muse, mutect2, varscan2
- OR2L2 | c.461A>C p.N154T | Missense Mutation (SNP) | VAF 13/183 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.449); called by muse, mutect2
- PEX2 | c.866G>A p.S289N | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- PKDREJ | c.4517C>G p.P1506R | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.467); called by muse, mutect2
- PREX2 | c.2255A>G p.D752G | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT tolerated, low confidence (0.89); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRG4 | c.614A>G p.K205R | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- PTPN13 | c.3071C>G p.S1024* | Nonsense Mutation (SNP) | VAF 8/33 reads (24%) | called by muse, mutect2, varscan2
- PTX4 | c.194A>G p.N65S (on ENST00000447419 / NM_001328608.2; = p.N60S on NM_001013658.1) | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- PUS7 | c.713G>A p.G238E | Missense Mutation (SNP) | VAF 38/83 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SATB2 | c.516T>G p.H172Q | Missense Mutation (SNP) | VAF 50/92 reads (54%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- SLC6A19 | c.769C>G p.P257A | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SRMS | c.1272G>C p.Q424H | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- TAOK3 | c.226T>G p.L76V | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- TAT | c.1270G>T p.E424* | Nonsense Mutation (SNP) | VAF 4/22 reads (18%) | called by muse, mutect2, varscan2
- TEKT4 | c.1119C>A p.N373K | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.76); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- TRIM51 | c.858A>T p.R286S | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- ZNF385D | c.700G>T p.A234S | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- AKAP4 | c.669A>G p.R223= | Silent (SNP) | VAF 23/75 reads (31%) | called by muse, mutect2, varscan2
- BCAS3 | c.1920C>T p.D640= (on ENST00000390652 / NM_001353144.2; = p.D625= on NM_017679.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 9/57 reads (16%) | catalogued as rs747433646, COSV66772952; called by muse, mutect2, varscan2
- CALCRL | c.1260T>G p.S420= | Silent (SNP) | VAF 13/57 reads (23%) | called by muse, mutect2, varscan2
- CCNE1 | c.720T>C p.R240= | Silent (SNP) | VAF 8/35 reads (23%) | called by muse, mutect2, varscan2
- CD1D | c.378C>T p.N126= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as rs772184982, COSV63809575; called by muse, mutect2, varscan2
- CR2 | c.2184G>A p.G728= | Silent (SNP) | VAF 5/22 reads (23%) | called by muse, mutect2
- CSMD2 | c.7560C>T p.S2520= | Silent (SNP) | VAF 12/43 reads (28%) | catalogued as COSV53898104, COSV53961351, COSV53975638; called by muse, mutect2, varscan2
- CTSE | c.1047C>T p.F349= (on ENST00000360218; = p.F344= on NM_001910.4) | Silent (SNP) | VAF 14/40 reads (35%) | catalogued as rs782007406, COSV63061414; called by muse, mutect2, varscan2
- DDX24 | c.1035C>T p.I345= | Silent (SNP) | VAF 11/77 reads (14%) | catalogued as rs750704452, COSV58213464; called by muse, mutect2, varscan2
- DIP2C | c.2652C>G p.T884= | Silent (SNP) | VAF 16/53 reads (30%) | called by muse, mutect2, varscan2
- EGR4 | c.1047C>T p.I349= (on ENST00000545030; = p.I246= on NM_001965.4) | Silent (SNP) | VAF 19/66 reads (29%) | catalogued as rs1452845256; called by muse, mutect2, varscan2
- FBN1 | c.3873C>T p.C1291= | Silent (SNP) | VAF 5/31 reads (16%) | called by muse, mutect2, varscan2
- GATAD2A | c.390C>T p.T130= | Silent (SNP) | VAF 9/23 reads (39%) | catalogued as rs773789441, COSV99389634; called by muse, mutect2, varscan2
- GCFC2 | c.1278A>G p.E426= | Silent (SNP) | VAF 12/75 reads (16%) | called by muse, mutect2, varscan2
- MUC17 | c.2679C>T p.S893= | Silent (SNP) | VAF 8/80 reads (10%) | called by muse, mutect2
- MYH2 | c.5208G>T p.L1736= | Silent (SNP) | VAF 10/46 reads (22%) | called by muse, mutect2, varscan2
- NLRP8 | c.654C>A p.I218= | Silent (SNP) | VAF 8/44 reads (18%) | called by muse, mutect2, varscan2
- OR56B1 | c.729A>T p.A243= | Silent (SNP) | VAF 6/47 reads (13%) | called by muse, mutect2, varscan2
- OR6A2 | c.978T>C p.N326= | Silent (SNP) | VAF 12/71 reads (17%) | catalogued as rs1423477116; called by muse, mutect2, varscan2
- PCDHB7 | c.1797C>T p.N599= | Silent (SNP) | VAF 26/137 reads (19%) | catalogued as rs782476678, COSV50763273; called by muse, mutect2, varscan2
- PCDHGA3 | c.216G>A p.T72= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as rs766061974, COSV53920201; called by muse, mutect2, varscan2
- PRB2 | c.636T>C p.P212= | Silent (SNP) | VAF 20/120 reads (17%) | catalogued as rs557500313, COSV101231361, COSV66983586; called by muse, mutect2, varscan2
- PROSER1 | c.1866A>G p.P622= | Silent (SNP) | VAF 11/71 reads (15%) | catalogued as rs1246026814; called by muse, mutect2, varscan2
- PRUNE2 | c.7326C>T p.N2442= | Silent (SNP) | VAF 12/34 reads (35%) | called by muse, mutect2, varscan2
- QTRT1 | c.834C>T p.F278= | Silent (SNP) | VAF 11/31 reads (35%) | catalogued as rs758269870, COSV51551507, COSV51552105; called by muse, mutect2, varscan2
- SARS1 | c.492C>T p.V164= | Silent (SNP) | VAF 16/94 reads (17%) | called by muse, mutect2, varscan2
- SCGB1A1 | c.267G>A p.L89= | Silent (SNP) | VAF 3/38 reads (8%) | called by muse, mutect2
- ST6GALNAC3 | c.258A>C p.S86= | Silent (SNP) | VAF 7/57 reads (12%) | called by muse, mutect2, varscan2
- TBL3 | c.234C>T p.N78= | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as rs756897051; called by muse, mutect2, varscan2
- TMEM109 | c.414C>G p.A138= | Silent (SNP) | VAF 19/114 reads (17%) | called by muse, mutect2, varscan2
- WNT7B | c.399C>T p.C133= | Silent (SNP) | VAF 17/50 reads (34%) | catalogued as rs368229070; called by muse, mutect2, varscan2
- ZNF507 | c.1794A>C p.T598= | Silent (SNP) | VAF 6/25 reads (24%) | called by muse, mutect2
- ZNF585B | c.2067T>G p.P689= | Silent (SNP) | VAF 11/60 reads (18%) | catalogued as COSV100459400; called by muse, mutect2, varscan2
- ERCC6 | c.1397+7312_1397+7314del | Intron (DEL) | VAF 10/63 reads (16%) | called by pindel, varscan2
- PARGP1 | n.833C>T | RNA (SNP) | VAF 13/65 reads (20%) | catalogued as rs782619031; called by muse, mutect2, varscan2
